Somatic mutation profile of tumor specimen TARGET-20-PARCZP-09A (aliquot TARGET-20-PARCZP-09A-01D) from TARGET case TARGET-20-PARCZP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,088 days).
Specimen TARGET-20-PARCZP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78567006-c3f9-4094-896f-55f47b6dcb62.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCZP-14A (Bone Marrow Normal), aliquot TARGET-20-PARCZP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70b34e9d-010b-45ee-840f-165241c8b6bb

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 108/254 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FCGBP | c.10960C>T p.R3654C | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs1336782101; called by muse, mutect2, varscan2
- MYH2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 128/262 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs765877777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASXL2 | c.1799_1802dup p.Q602Tfs*7 | Frame Shift Ins (INS) | VAF 70/183 reads (38%) | called by mutect2, pindel, varscan2
- IKZF1 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAD21 | c.1113dup p.L372Tfs*12 | Frame Shift Ins (INS) | VAF 108/316 reads (34%) | called by mutect2, pindel, varscan2
